Gene-level copy-number profile of tumor specimen ALCH-AE5J-TTP1-A from ALCHEMIST case ALCH-AE5J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.1 years (23,794 days).
Specimen ALCH-AE5J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc2dc9cb-347f-4993-b0c4-696d5cbb8f0f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE5J-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/dcd1da41-7cb4-4a7b-8875-f2dafe34b135

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,931; copy number 2: 55,347; copy number 3: 556; copy number 4: 4; copy number 5: 2; copy number 7: 45; copy number 8: 3; copy number 9: 1; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:134,506,552–134,518,092, 2 genes: LINC01843, RN7SL541P.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–2): UCKL1, MIR1914, MIR647, UCKL1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,516,588–58,244,865, 45 genes, copy number 7 (within-gene range 3–7): DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr14:105,597,691–105,601,728, 1 gene, copy number 9 (within-gene range 1–9): IGHE.
- chr16:2,603,350–2,645,214, 4 genes, copy number 8–12: AC141586.1, PDPK2P, AC141586.4, AC141586.2.
- chr20:64,290,187–64,313,132, 2 genes, copy number 5: CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 183. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
